Somatic mutation profile of tumor specimen TCGA-FV-A3I0-01A (aliquot TCGA-FV-A3I0-01A-11D-A22F-10) from TCGA case TCGA-FV-A3I0, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, fibrolamellar; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 76.9 years (28,101 days).
Specimen TCGA-FV-A3I0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6abbac7b-33b8-453c-b649-f4d1d553d1ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FV-A3I0-11A (Solid Tissue Normal), aliquot TCGA-FV-A3I0-11A-11D-A22F-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25af6e5d-d588-4065-936b-bd1c4535f6a7

The open-access MAF lists 98 somatic variants for this specimen: 71 protein-altering or splice-affecting, 20 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 20, Intron 4, Nonsense Mutation 3, Frame Shift Del 2, 5'UTR 2, In Frame Del 1, Splice Region 1, 3'UTR 1, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA1 | c.6479G>C p.G2160A | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV101036700, COSV66070657; called by muse, mutect2, varscan2
- ABCC10 | c.2005G>A p.A669T (on ENST00000372530 / NM_001198934.2; = p.A641T on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.499); catalogued as COSV55093952; called by muse, mutect2, varscan2
- ADAM8 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.343); catalogued as COSV69865333; called by mutect2, varscan2
- APBB1 | c.1520G>C p.R507P | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs142613637; called by muse, mutect2, varscan2
- ASIC5 | c.290A>T p.E97V | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.021); catalogued as COSV72232566; called by muse, mutect2, varscan2
- ATAD2 | c.1661C>T p.T554I | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54886659; called by muse, mutect2, varscan2
- CCDC168 | c.10908C>A p.F3636L | Missense Mutation (SNP) | VAF 75/190 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV59425773; called by muse, mutect2, varscan2
- CDCA7 | c.922G>A p.E308K (on ENST00000347703 / NM_145810.3; = p.E387K on NM_031942.5) | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV60721834; called by muse, mutect2, varscan2
- CLK4 | c.80A>G p.H27R | Missense Mutation (SNP) | VAF 66/121 reads (55%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV60321086; called by muse, mutect2, varscan2
- CPA6 | c.54C>A p.C18* | Nonsense Mutation (SNP) | VAF 27/72 reads (38%) | catalogued as COSV52742675; called by muse, mutect2, varscan2
- DCAF8L2 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 58/65 reads (89%) | SIFT tolerated (0.67); PolyPhen benign (0.01); catalogued as COSV70552709, COSV70552884; called by muse, mutect2, varscan2
- DGAT1 | c.1417G>A p.V473I | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.793); catalogued as rs782605643, COSV60049344; called by muse, mutect2, varscan2
- DPYSL5 | c.755C>T p.S252L | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as rs372829541; called by muse, mutect2, varscan2
- DYNC1H1 | c.12742G>T p.A4248S | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1012807291, COSV64142455; called by muse, mutect2
- DYSF | c.5197A>G p.I1733V | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV50584467; called by muse, mutect2, varscan2
- ELOA | c.1264A>G p.M422V | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV69311349; called by muse, mutect2, varscan2
- FGFR2 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 43/75 reads (57%) | SIFT tolerated (0.39); PolyPhen benign (0.023); catalogued as COSV60656744; called by muse, mutect2, varscan2
- FHDC1 | c.2276G>A p.S759N | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.15); catalogued as COSV52602963; called by muse, mutect2, varscan2
- FLG2 | c.2687G>A p.G896D | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.171); catalogued as COSV66173358; called by muse, mutect2, varscan2
- HERC4 | c.458C>G p.S153C | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV53275300, COSV99517605; called by muse, mutect2, varscan2
- HK2 | c.2200C>T p.L734F | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV51879646; called by muse, mutect2, varscan2
- HTT | c.7381C>T p.R2461C | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764639811, COSV61857079; called by muse, mutect2, varscan2
- IGSF5 | c.170G>T p.R57L | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV66031402; called by muse, mutect2, varscan2
- KMT5B | c.2572T>G p.L858V | Missense Mutation (SNP) | VAF 96/172 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58569683; called by muse, mutect2, varscan2
- KTN1 | c.331G>T p.V111F | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs1261444785, COSV68025592; called by muse, mutect2, varscan2
- LAP3 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.984); catalogued as COSV56901832; called by muse, mutect2
- MED25 | c.306G>T p.K102N | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV57207360, COSV57207728; called by muse, mutect2, varscan2
- MPDZ | c.5991A>T p.L1997F (on ENST00000319217 / NM_001330637.2; = p.L1968F on NM_003829.5) | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59924518; called by muse, mutect2, varscan2
- MUC5B | c.16225G>A p.V5409M | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs915602595, COSV71595519; called by muse, mutect2, varscan2
- NLRC3 | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 37/54 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1222465640, COSV57095970; called by muse, mutect2, varscan2
- OR2D3 | c.595G>T p.A199S | Missense Mutation (SNP) | VAF 129/254 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.431); catalogued as COSV53494968; called by muse, mutect2, varscan2
- PBRM1 | c.4828T>C p.Y1610H (on ENST00000296302 / NM_001366071.2; = p.Y1503H on NM_018313.5) | Missense Mutation (SNP) | VAF 28/36 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56304110; called by muse, mutect2, varscan2
- PIWIL1 | c.156G>C p.Q52H | Missense Mutation (SNP) | VAF 34/209 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV55351970; called by muse, mutect2, varscan2
- PKHD1L1 | c.9566T>A p.V3189E | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65753003; called by muse, mutect2, varscan2
- PLB1 | c.2772C>T p.A924= | Splice Region (SNP) | VAF 10/27 reads (37%) | catalogued as COSV59835545; called by muse, mutect2, varscan2
- PRB1 | c.453+2G>A | Missense Mutation (SNP) | VAF 14/111 reads (13%) | catalogued as rs199764037, COSV53702943; called by muse, varscan2
- PRKAA1 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 25/251 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780617578, COSV57183601; called by muse, mutect2, varscan2
- PSMF1 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV55676053, COSV99850406; called by muse, mutect2, varscan2
- RARG | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754842832, COSV58433586; called by muse, mutect2, varscan2
- RIN3 | c.1423C>T p.P475S | Missense Mutation (SNP) | VAF 21/27 reads (78%) | SIFT tolerated (0.2); PolyPhen benign (0.158); catalogued as COSV53655606; called by muse, mutect2, varscan2
- S100A7 | c.267G>T p.Q89H | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV64193765; called by muse, mutect2, varscan2
- SAAL1 | c.46G>C p.E16Q | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.055); catalogued as COSV55517266; called by muse, mutect2
- SAMSN1 | c.967G>T p.D323Y | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV53477616; called by muse, mutect2, varscan2
- SESN1 | c.860G>T p.R287L (on ENST00000356644 / NM_001199933.1; = p.R346L on NM_014454.3) | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV57421993; called by muse, mutect2, varscan2
- SLC35C1 | c.538G>A p.G180S | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58480877; called by muse, mutect2, varscan2
- SMC6 | c.2500C>T p.R834* | Nonsense Mutation (SNP) | VAF 18/106 reads (17%) | catalogued as COSV61178404; called by muse, mutect2, varscan2
- SNX8 | c.785C>A p.A262E | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV56130129; called by muse, mutect2, varscan2
- SP4 | c.1505G>C p.S502T | Missense Mutation (SNP) | VAF 90/166 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.441); catalogued as COSV56026510; called by muse, mutect2, varscan2
- STARD7 | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV61526780; called by muse, mutect2, varscan2
- STIM1 | c.462C>A p.F154L | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV56158975, COSV56160643; called by muse, mutect2, varscan2
- TACC2 | c.1936G>T p.G646W | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.877); catalogued as COSV57751867, COSV57772963; called by muse, mutect2, varscan2
- TEPSIN | c.1148C>G p.P383R | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56144890; called by muse, mutect2, varscan2
- THADA | c.5795T>G p.L1932R | Missense Mutation (SNP) | VAF 61/127 reads (48%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); catalogued as COSV56700184; called by muse, mutect2, varscan2
- TRIP4 | c.779A>G p.E260G | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV56033488; called by muse, mutect2, varscan2
- TTBK1 | c.1043G>C p.G348A | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV52496569; called by muse, mutect2
- UBE2S | c.40C>T p.R14C | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs374069290; called by muse, mutect2, varscan2
- USH2A | c.11309C>G p.S3770* | Nonsense Mutation (SNP) | VAF 12/79 reads (15%) | catalogued as COSV56328714, COSV56420066, COSV56436249; called by muse, mutect2, varscan2
- USH2A | c.1630A>G p.T544A | Missense Mutation (SNP) | VAF 87/114 reads (76%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100231784, COSV56436272; called by muse, mutect2, varscan2
- WNK2 | c.4913A>G p.D1638G (on ENST00000297954 / NM_001282394.1; = p.D1601G on NM_006648.3) | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as COSV52960655; called by muse, mutect2, varscan2
- ZIM3 | c.794C>G p.S265C | Missense Mutation (SNP) | VAF 30/221 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV54142024, COSV54143836, COSV54146692; called by muse, mutect2, varscan2
- ZNF551 | c.1982A>G p.H661R | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs928172581, COSV56595116; called by muse, mutect2, varscan2
- ZNF578 | c.1356G>T p.E452D | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as rs779530711, COSV69736938; called by muse, mutect2, varscan2
- ZNF777 | c.487G>C p.D163H | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.656); catalogued as COSV56100100; called by muse, mutect2, varscan2
- ZNF841 | c.3G>T p.M1? (on ENST00000426391 / NM_001369830.1; = p.M117I on NM_001136499.1 and 6 other RefSeq transcripts) | Translation Start Site (SNP) | VAF 39/263 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV63471661; called by muse, mutect2, varscan2
- ZSCAN4 | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 85/151 reads (56%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV59001688; called by muse, mutect2, varscan2
- BBS9 | c.2297del p.L766Wfs*15 (on ENST00000242067 / NM_001348036.1; = p.L726Wfs*15 on NM_014451.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- CMAS | c.232_242del p.A78Ffs*14 | Frame Shift Del (DEL) | VAF 38/80 reads (48%) | called by mutect2, pindel, varscan2
- GPT2 | c.1009C>T p.H337Y | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.412); called by muse, mutect2
- KIR3DL3 | c.691G>A p.G231S | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- SLC27A3 | c.1440_1457del p.K480_G486delinsN (on ENST00000271857; = p.K352_G358delinsN on NM_024330.4 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 8/68 reads (12%) | called by mutect2, varscan2
- UTP20 | c.4132_4133dup p.Q1378Hfs*5 | Frame Shift Ins (INS) | VAF 44/113 reads (39%) | called by mutect2, pindel, varscan2
- ALOX12B | c.1197G>A p.L399= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as COSV59876456; called by muse, mutect2
- ANKRD30A | c.3154T>C p.L1052= (on ENST00000611781; = p.L996= on NM_052997.2) | Silent (SNP) | VAF 46/211 reads (22%) | catalogued as COSV64621311; called by muse, mutect2, varscan2
- CLEC4F | c.828T>C p.N276= | Silent (SNP) | VAF 104/201 reads (52%) | catalogued as COSV55481587; called by muse, mutect2, varscan2
- DCSTAMP | c.312G>T p.G104= | Silent (SNP) | VAF 25/149 reads (17%) | catalogued as COSV52580169; called by muse, mutect2, varscan2
- ETV3L | c.90C>T p.A30= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as rs750838692, COSV71901203; called by muse, mutect2, varscan2
- HPS5 | c.159A>G p.G53= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV62540651; called by muse, mutect2, varscan2
- KCNN1 | c.810G>A p.T270= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as rs374014650; called by muse, mutect2, varscan2
- KDM6B | c.4188C>T p.F1396= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as rs758374059, COSV54687004; called by muse, mutect2, varscan2
- MRFAP1 | c.138C>T p.H46= | Silent (SNP) | VAF 84/111 reads (76%) | catalogued as rs1443742205, COSV57995243; called by muse, mutect2, varscan2
- MT1F | c.87C>T p.C29= | Silent (SNP) | VAF 24/40 reads (60%) | catalogued as COSV57622648; called by muse, mutect2, varscan2
- N4BP1 | c.864T>A p.S288= | Silent (SNP) | VAF 42/65 reads (65%) | catalogued as COSV52213319; called by muse, mutect2, varscan2
- OR51T1 | c.886T>C p.L296= | Silent (SNP) | VAF 8/138 reads (6%) | catalogued as COSV59028121; called by muse, mutect2
- RGPD4 | c.2832T>C p.D944= | Silent (SNP) | VAF 161/1009 reads (16%) | catalogued as rs781250584, COSV61749719; called by muse, mutect2, varscan2
- SEC16A | c.1893G>T p.V631= | Silent (SNP) | VAF 32/44 reads (73%) | catalogued as COSV51540638; called by muse, mutect2, varscan2
- SLC17A6 | c.1587G>T p.G529= | Silent (SNP) | VAF 36/127 reads (28%) | catalogued as rs770305192, COSV54141330; called by muse, mutect2, varscan2
- SLCO2A1 | c.1782C>T p.C594= | Silent (SNP) | VAF 31/112 reads (28%) | catalogued as rs751921800, COSV60487279; called by muse, mutect2, varscan2
- STYXL2 | c.1965G>C p.G655= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as COSV54810107; called by muse, mutect2, varscan2
- TGFBRAP1 | c.2238C>T p.T746= | Silent (SNP) | VAF 40/106 reads (38%) | catalogued as rs763610405, COSV51516326; called by muse, mutect2, varscan2
- UBXN7 | c.1104G>A p.E368= | Silent (SNP) | VAF 38/67 reads (57%) | catalogued as COSV56357774; called by muse, mutect2, varscan2
- UFL1 | c.1077C>T p.S359= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as rs199861765, COSV100990132, COSV65150168; called by muse, mutect2, varscan2
- CTBP1 | c.41-3041T>A | Intron (SNP) | VAF 69/95 reads (73%) | catalogued as COSV99338172; called by muse, mutect2, varscan2
- KLHL9 | c.-142C>T | 5'UTR (SNP) | VAF 8/21 reads (38%) | catalogued as COSV100757172; called by muse, mutect2, varscan2
- KLHL9 | c.-143G>T | 5'UTR (SNP) | VAF 8/20 reads (40%) | catalogued as COSV100757173; called by muse, mutect2, varscan2
- PMEPA1 | c.109+9301C>T | Intron (SNP) | VAF 21/54 reads (39%) | catalogued as rs1206498885; called by muse, mutect2, varscan2
- SEC14L2 | c.55-916C>G | Intron (SNP) | VAF 11/126 reads (9%) | called by muse, mutect2
- STX4 | c.133-16C>T | Intron (SNP) | VAF 31/59 reads (53%) | catalogued as rs1335783742, COSV58268745; called by muse, mutect2, varscan2
- TMEM140 | c.*659C>T | 3'UTR (SNP) | VAF 15/88 reads (17%) | catalogued as COSV99313333; called by muse, mutect2, varscan2
